Somatic mutation profile of tumor specimen 0DMEUB from CCDI case PBCAKP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 20.0 years (7,315 days).
Specimen 0DMEUB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f96be48-0325-47fa-bf0f-f5458e3cddb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMEUK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa9c880a-0c3c-4027-93e3-f1dd25a7341c

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1B1 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 64/292 reads (22%) | catalogued as COSV58015669; called by muse, varscan2
- GSTA1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs148795539; called by muse, mutect2, varscan2
- CCNL1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR10A4 | c.771C>T p.I257= | Silent (SNP) | VAF 113/238 reads (47%) | catalogued as COSV65842392; called by muse, mutect2, varscan2
- EWSR1 | c.974+77G>A | Intron (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- MKS1 | c.262-89T>C | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, varscan2
- PPIL1 | c.57-53C>T | Intron (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
